Gene-level copy-number profile of tumor specimen TCGA-IE-A3OV-01A from TCGA case TCGA-IE-A3OV, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 42.7 years (15,607 days).
Specimen TCGA-IE-A3OV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.25af3703-371a-4276-bf75-61b84e613ccc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IE-A3OV-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8b0d24ec-4e88-49be-b546-2a78f79ad30d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 3,141; copy number 2: 15,324; copy number 3: 20,121; copy number 4: 12,202; copy number 5: 7,708; copy number 6: 1,259.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IE-A3OV-01A-11D-A227-01): tumor purity 0.78, ploidy 3.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,974,967–49,209,779, 6 genes: AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1.
- chr13:49,444,374–50,906,856, 33 genes (within-gene range 0–1): SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11, EBPL, KPNA3, AL136301.1, RNY4P30, CTAGE10P, RNY4P9, SPRYD7, DLEU2, TRIM13, MIR3613, KCNRG, AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5, DLEU1, AL137060.6, RPL18P10, AL137060.1, AL137060.3, ST13P4, RPL34P26, AL158195.1.
- chr18:48,026,672–48,863,217, 10 genes (within-gene range 0–2): ZBTB7C, AC105101.1, AC105101.2, RNU6-708P, C18orf12, RNA5SP456, AC024288.1, POLR3GP2, CTIF, AC048380.2.
- chr18:48,826,051–48,952,052, 2 genes: AC093567.1, SMAD7.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,642. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
